Somatic mutation profile of tumor specimen C3L-06231-01 (aliquot CPT0505100006) from CPTAC case C3L-06231, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.3 years (27,130 days).
Specimen C3L-06231-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14a83a77-3684-4d6b-b9b7-990e71c67445.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06231-31 (Blood Derived Normal), aliquot CPT0505090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/303d57c1-2bcc-43d2-96fa-fec2ff65dd4b

The open-access MAF lists 507 somatic variants for this specimen: 398 protein-altering or splice-affecting, 93 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 93, Frame Shift Ins 33, Nonsense Mutation 24, Frame Shift Del 13, Intron 9, 5'Flank 2, Splice Site 2, Splice Region 2, 3'UTR 2, Translation Start Site 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALOX12B | c.1350del p.L451Sfs*16 | Frame Shift Del (DEL) | VAF 72/485 reads (15%) | catalogued as rs746723399, COSV59872823; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 65/456 reads (14%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- B2M | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 118/416 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as rs1023835002, COSV62562840, COSV62562870, COSV62563658; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 64/374 reads (17%) | catalogued as rs1253151209, CM123456, COSV56236427; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 50/296 reads (17%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- PDX1 | c.217dup p.L73Pfs*152 | Frame Shift Ins (INS) | VAF 102/580 reads (18%) | catalogued as rs1445970498; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1634A>G p.E545G | Missense Mutation (SNP) | VAF 37/363 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACCS | c.1314_1316del p.N438del | In Frame Del (DEL) | VAF 50/444 reads (11%) | catalogued as rs780954149; called by pindel, varscan2
- ADAD2 | c.1076G>A p.G359D (on ENST00000315906 / NM_001145400.2; = p.G441D on NM_139174.4) | Missense Mutation (SNP) | VAF 89/513 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as rs1158752661; called by muse, mutect2, varscan2
- ADAMTS17 | c.938A>G p.E313G | Missense Mutation (SNP) | VAF 118/426 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs781175879; called by muse, mutect2, varscan2
- ADCY8 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 75/591 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs771490152; called by muse, mutect2, varscan2
- ADGRB2 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 125/392 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1019036110; called by muse, mutect2, varscan2
- AFF2 | c.2637G>T p.L879F | Missense Mutation (SNP) | VAF 206/385 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53991474; called by muse, mutect2, varscan2
- AGAP2 | c.2840T>C p.V947A (on ENST00000547588 / NM_001122772.2; = p.V591A on NM_014770.4) | Missense Mutation (SNP) | VAF 63/499 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.097); catalogued as rs1453949815; called by muse, mutect2, varscan2
- AGAP3 | c.1400C>T p.S467L (on ENST00000622464; = p.S503L on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/504 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs151283982; called by muse, mutect2, varscan2
- AGRN | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 42/527 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs559237289; called by muse, mutect2
- AGXT | c.601G>T p.D201Y | Missense Mutation (SNP) | VAF 52/386 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56756318; called by muse, mutect2, varscan2
- AKAP3 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as rs753084527; called by muse, mutect2, varscan2
- AKAP6 | c.5161C>T p.R1721C | Missense Mutation (SNP) | VAF 61/371 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as rs758563777, COSV55209326; called by muse, mutect2, varscan2
- ALKBH3 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs202134415; called by muse, mutect2, varscan2
- ANKRD30A | c.1515A>C p.K505N (on ENST00000611781; = p.K449N on NM_052997.2) | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.341); catalogued as COSV64612384; called by muse, mutect2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 99/618 reads (16%) | catalogued as rs773922861; called by mutect2, pindel, varscan2
- ARMC9 | c.2174G>T p.R725L | Missense Mutation (SNP) | VAF 79/549 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs768217263; called by muse, mutect2, varscan2
- CACTIN | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 56/406 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777040239; called by muse, mutect2, varscan2
- CAPN2 | c.2078_2079del p.S693Lfs*11 | Frame Shift Del (DEL) | VAF 65/450 reads (14%) | catalogued as rs1309102893; called by pindel, varscan2
- CAPSL | c.525+4A>G | Splice Region (SNP) | VAF 74/510 reads (15%) | catalogued as COSV101274144; called by muse, mutect2, varscan2
- CAVIN2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 81/541 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.104); catalogued as rs762124159, COSV58423626; called by muse, mutect2, varscan2
- CDH1 | c.1320G>A p.K440= | Splice Region (SNP) | VAF 41/232 reads (18%) | catalogued as COSV55728800, COSV55733458; called by muse, mutect2, varscan2
- CDH13 | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 54/491 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1417908809; called by muse, mutect2, varscan2
- CDH8 | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 75/515 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs750650661, COSV54903558; called by muse, mutect2, varscan2
- CEP41 | c.653A>G p.H218R | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.143); catalogued as rs527896814; called by muse, mutect2, varscan2
- CETN1 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 100/544 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.449); catalogued as rs1435269652; called by muse, mutect2, varscan2
- CFTR | c.1085A>G p.Y362C | Missense Mutation (SNP) | VAF 44/323 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV50097309; called by muse, mutect2, varscan2
- CHRNA7 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 52/214 reads (24%) | catalogued as CM1514292, COSV60968905; called by muse, mutect2, varscan2
- CHRNG | c.1010A>G p.H337R | Missense Mutation (SNP) | VAF 25/476 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CD166273, COSV104432083; called by muse, mutect2
- COG5 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1037267212; called by muse, varscan2
- COIL | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 66/477 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.173); catalogued as rs756922685; called by muse, mutect2, varscan2
- COL5A1 | c.3899G>C p.G1300A | Missense Mutation (SNP) | VAF 79/549 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100880787; called by muse, mutect2, varscan2
- COL9A1 | c.2074dup p.E692Gfs*16 | Frame Shift Ins (INS) | VAF 45/246 reads (18%) | catalogued as rs753414405; called by mutect2, pindel, varscan2
- CPNE2 | c.727G>T p.G243C | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51960835; called by muse, mutect2, varscan2
- CRNN | c.972G>T p.Q324H | Missense Mutation (SNP) | VAF 107/666 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55122096, COSV55124051; called by muse, mutect2, varscan2
- CSMD1 | c.2261G>A p.R754H (on ENST00000520002; = p.R753H on NM_033225.6) | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs748646070, COSV100148839, COSV59366434; called by muse, mutect2
- CSMD1 | c.2203G>A p.E735K (on ENST00000520002; = p.E734K on NM_033225.6) | Missense Mutation (SNP) | VAF 63/464 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1200912441, COSV59281566; called by muse, mutect2, varscan2
- CTNND2 | c.1351G>A p.G451S | Missense Mutation (SNP) | VAF 52/345 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs150121479, COSV58875865; called by muse, mutect2, varscan2
- CYP1A2 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 140/470 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367858322; called by muse, mutect2, varscan2
- DOK3 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 65/364 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs368466434; called by muse, mutect2, varscan2
- DPAGT1 | c.71C>A p.A24D | Missense Mutation (SNP) | VAF 30/577 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.287); catalogued as COSV100830703; called by muse, mutect2
- DSCAM | c.5804G>T p.R1935L | Missense Mutation (SNP) | VAF 65/517 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.982); catalogued as COSV99064481; called by muse, mutect2, varscan2
- DSP | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 64/451 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777782794, COSV101131282; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ECM1 | c.624G>T p.E208D | Missense Mutation (SNP) | VAF 52/451 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV60873725; called by muse, mutect2, varscan2
- EIF3A | c.3686G>C p.R1229T | Missense Mutation (SNP) | VAF 45/387 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.057); catalogued as COSV64960497; called by muse, mutect2, varscan2
- ELFN2 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 69/525 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs1458341417; called by muse, mutect2, varscan2
- EMILIN2 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 85/501 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs546388595, COSV54420420; called by muse, mutect2, varscan2
- EPX | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 76/380 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1248374190; called by muse, mutect2, varscan2
- FAM160B2 | c.1562T>C p.L521P | Missense Mutation (SNP) | VAF 65/493 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1432676600; called by muse, mutect2, varscan2
- FAM184B | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 76/605 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1160276217, COSV99401210; called by muse, mutect2, varscan2
- FGD1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 142/257 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs757230624; called by muse, varscan2
- FIGNL2 | c.635C>T p.A212V | Missense Mutation (SNP) | VAF 32/536 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.059); catalogued as rs1209683015; called by muse, mutect2
- FTHL17 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 96/278 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs756401411; called by muse, mutect2, varscan2
- GAS6 | c.449dup p.R151Pfs*27 | Frame Shift Ins (INS) | VAF 55/385 reads (14%) | catalogued as rs773341392; called by mutect2, varscan2
- GDA | c.760T>G p.L254V | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV52992212, COSV99429796; called by muse, mutect2, varscan2
- GNRH1 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 36/319 reads (11%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.531); catalogued as COSV99373616; called by muse, mutect2, varscan2
- GPR149 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 86/634 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs763187151; called by muse, mutect2, varscan2
- GPT | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 88/588 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1418881972; called by muse, mutect2, varscan2
- GREM2 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 58/410 reads (14%) | catalogued as rs753407682, COSV100547923, COSV100547973; called by muse, mutect2, varscan2
- HCK | c.9dup p.R4_?3 | Frame Shift Ins (INS) | VAF 72/406 reads (18%) | catalogued as rs755024531; called by mutect2, varscan2
- HIP1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 53/327 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs782619030; called by muse, mutect2, varscan2
- HNMT | c.731dup p.L244Ffs*3 | Frame Shift Ins (INS) | VAF 69/461 reads (15%) | catalogued as rs752033631; called by mutect2, pindel, varscan2
- HYDIN | c.10077dup p.L3360Afs*6 | Frame Shift Ins (INS) | VAF 39/320 reads (12%) | catalogued as rs781576725; called by mutect2, pindel, varscan2
- ICE2 | c.2801A>G p.D934G | Missense Mutation (SNP) | VAF 85/270 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs375398086; called by muse, mutect2, varscan2
- INPP5J | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 70/626 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.867); catalogued as rs546001465, COSV58513171; called by muse, mutect2, varscan2
- ITGB4 | c.1085C>T p.A362V | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs531539918, COSV52323336; called by muse, varscan2
- KANK2 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs1017278098; called by muse, mutect2, varscan2
- KDM5D | c.2293A>G p.N765D | Missense Mutation (SNP) | VAF 76/238 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.627); catalogued as rs1238692765; called by muse, mutect2, varscan2
- KIAA1549L | c.3430G>A p.A1144T (on ENST00000321505; = p.A1441T on NM_012194.3) | Missense Mutation (SNP) | VAF 64/498 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.869); catalogued as rs373127794; called by muse, mutect2, varscan2
- KIF19 | c.856G>A p.A286T | Missense Mutation (SNP) | VAF 79/461 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373944198; called by muse, mutect2, varscan2
- KIF5C | c.2168A>G p.D723G | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as rs1161343221; called by muse, mutect2, varscan2
- KIFC2 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 38/754 reads (5%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs746892737; called by muse, mutect2
- KRT71 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 55/411 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as rs201441729; called by muse, mutect2, varscan2
- LDB3 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 77/501 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs758182278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC74A | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 40/281 reads (14%) | catalogued as rs200189415, COSV99372215; called by muse, mutect2, varscan2
- MAP1S | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 119/697 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs951952247; called by muse, mutect2, varscan2
- MARF1 | c.4967G>A p.R1656H | Missense Mutation (SNP) | VAF 65/438 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1035129157, COSV60026510; called by muse, mutect2, varscan2
- MEGF8 | c.3344A>G p.N1115S (on ENST00000251268 / NM_001271938.2; = p.N1048S on NM_001410.3) | Missense Mutation (SNP) | VAF 55/572 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs767539999; called by muse, mutect2, varscan2
- MGAT3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 83/552 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as rs760106779, COSV57864375, COSV57865845; called by muse, mutect2, varscan2
- MMP3 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 41/358 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.533); catalogued as rs536550929; called by muse, mutect2, varscan2
- MMRN2 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 90/482 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs753210428; called by muse, mutect2, varscan2
- MOBP | c.264dup p.A89Rfs*16 (on ENST00000420739; = p.A113Rfs*16 on NM_001278322.2) | Frame Shift Ins (INS) | VAF 84/676 reads (12%) | catalogued as rs745367846; called by mutect2, pindel, varscan2
- MPZL3 | c.59T>C p.V20A | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs781679842; called by muse, mutect2, varscan2
- MRGPRX1 | c.853C>T p.Q285* | Nonsense Mutation (SNP) | VAF 75/843 reads (9%) | catalogued as COSV100245875; called by muse, mutect2
- MRI1 | c.874G>A p.G292S (on ENST00000040663 / NM_001031727.4; = p.G245S on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/483 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs923199210, COSV50005516; called by muse, mutect2, varscan2
- MRPS12 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 86/609 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as rs766262829; called by muse, varscan2
- MSC | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 65/617 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); catalogued as COSV57697663; called by muse, mutect2, varscan2
- MSH6 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 71/431 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs370157832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTNR1B | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 85/620 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1565177580; called by muse, mutect2, varscan2
- MTUS1 | c.2024C>A p.S675Y | Missense Mutation (SNP) | VAF 55/417 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as COSV50550746; called by muse, mutect2, varscan2
- MXD4 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 76/506 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as rs756491716; called by muse, mutect2, varscan2
- MYH6 | c.4306C>T p.R1436C | Missense Mutation (SNP) | VAF 89/502 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746893658; called by muse, mutect2, varscan2
- MYO9A | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 117/391 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201188859; called by muse, mutect2, varscan2
- NHSL1 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 22/457 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.467); catalogued as rs769522991; called by muse, mutect2
- NHSL1 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 67/485 reads (14%) | catalogued as rs1260010068, COSV100607244; called by muse, mutect2, varscan2
- NPIPB2 | c.878C>T p.A293V (on ENST00000399147; = p.A153V on NM_001355514.1) | Missense Mutation (SNP) | VAF 46/1001 reads (5%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.014); catalogued as rs780293021, COSV63638741; called by muse, mutect2
- NR4A3 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 126/737 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV58246258; called by muse, varscan2
- OR3A2 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 75/512 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.133); catalogued as rs369290823; called by muse, mutect2, varscan2
- OR4X2 | c.871A>G p.K291E | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs1355441685; called by muse, mutect2, varscan2
- OR5A2 | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 20/460 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as rs1347311391, COSV57391783; called by muse, mutect2
- OR5P2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 57/436 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs1355288762, COSV61489982; called by muse, mutect2, varscan2
- OR7A5 | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.304); catalogued as COSV59235352; called by muse, mutect2, varscan2
- OXCT2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 25/473 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as rs1265280065; called by muse, mutect2
- PAFAH2 | c.928C>A p.L310I | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100959299; called by muse, mutect2
- PBRM1 | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 43/282 reads (15%) | catalogued as COSV56276994; called by muse, mutect2, varscan2
- PCDHA3 | c.1849G>A p.G617S | Missense Mutation (SNP) | VAF 56/397 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.037); catalogued as rs1554122549, COSV63544329; called by muse, mutect2, varscan2
- PDE6B | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 55/391 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.178); catalogued as COSV99726846; called by muse, mutect2, varscan2
- PDZD7 | c.2042G>A p.G681D | Missense Mutation (SNP) | VAF 61/469 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV64651239; called by muse, mutect2, varscan2
- PDZRN3 | c.2839G>A p.A947T | Missense Mutation (SNP) | VAF 102/590 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs560895860, COSV55195692; called by muse, mutect2, varscan2
- PEX5 | c.1496A>G p.N499S (on ENST00000420616; = p.N491S on NM_000319.5) | Missense Mutation (SNP) | VAF 133/549 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1168577755; called by muse, mutect2, varscan2
- PGM1 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 124/433 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs747394265, COSV64301051; called by muse, varscan2
- PHGR1 | c.109dup p.H37Pfs*50 | Frame Shift Ins (INS) | VAF 66/360 reads (18%) | catalogued as rs1264440278; called by mutect2, varscan2
- PHTF1 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs746259493; called by muse, mutect2, varscan2
- PKD1L1 | c.7798G>A p.D2600N | Missense Mutation (SNP) | VAF 49/332 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV51845494; called by muse, mutect2, varscan2
- PLCL1 | c.2575C>T p.R859C | Missense Mutation (SNP) | VAF 69/354 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1278187587, COSV70876257; called by muse, mutect2, varscan2
- POM121L12 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 119/753 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV68692577; called by muse, varscan2
- PPFIA4 | c.3446G>A p.R1149H (on ENST00000447715; = p.R1150H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/609 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1381668960, COSV55314436; called by muse, mutect2, varscan2
- PPL | c.3569A>G p.N1190S | Missense Mutation (SNP) | VAF 88/554 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99278350; called by muse, varscan2
- PPP1R16B | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 46/332 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs773154570, COSV55381303; called by muse, mutect2, varscan2
- PPP1R37 | c.1973dup p.S659Qfs*37 | Frame Shift Ins (INS) | VAF 88/719 reads (12%) | catalogued as rs1205306229; called by mutect2, pindel, varscan2
- PRAMEF10 | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 67/303 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs747018020; called by muse, mutect2, varscan2
- PRICKLE2 | c.907T>G p.F303V (on ENST00000295902; = p.F247V on NM_198859.4) | Missense Mutation (SNP) | VAF 57/421 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55771852; called by muse, mutect2, varscan2
- PRSS36 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 38/328 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51638653; called by muse, mutect2, varscan2
- PTPRD | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs376714429; called by muse, mutect2, varscan2
- PTPRO | c.2137A>G p.T713A | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV55503664; called by muse, mutect2, varscan2
- PXN | c.1417G>A p.A473T (on ENST00000228307 / NM_001080855.3; = p.A439T on NM_002859.4) | Missense Mutation (SNP) | VAF 50/524 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs766217902, COSV57220123; called by muse, mutect2
- RFX4 | c.2048C>T p.T683M (on ENST00000392842 / NM_213594.3; = p.T589M on NM_032491.6) | Missense Mutation (SNP) | VAF 111/561 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs201038598; called by muse, mutect2, varscan2
- RIPK2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.358); catalogued as COSV55132129, COSV55132383; called by muse, mutect2, varscan2
- RIPK2 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs201291360; called by muse, varscan2
- SELPLG | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 48/988 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.407); catalogued as rs765784409; called by muse, mutect2
- SEMA4F | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 72/418 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as rs764308747, COSV60284502; called by muse, mutect2, varscan2
- SGK3 | c.189dup p.Q64Tfs*17 | Frame Shift Ins (INS) | VAF 19/196 reads (10%) | catalogued as rs1563636611; called by mutect2, varscan2
- SGSM3 | c.1458G>T p.K486N | Missense Mutation (SNP) | VAF 71/511 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1304692315, COSV99960658; called by muse, mutect2, varscan2
- SH3TC1 | c.674C>T p.T225M | Missense Mutation (SNP) | VAF 48/658 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs766716993, COSV55285873; called by muse, mutect2
- SIGLEC12 | c.979C>T p.L327F (on ENST00000291707 / NM_053003.4; = p.L209F on NM_033329.2) | Missense Mutation (SNP) | VAF 48/864 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs778382810; called by muse, mutect2
- SLAMF1 | c.675G>A p.W225* | Nonsense Mutation (SNP) | VAF 59/407 reads (14%) | catalogued as COSV99349184; called by muse, mutect2, varscan2
- SLC22A7 | c.898C>A p.H300N (on ENST00000372585 / NM_153320.2; = p.H298N on NM_006672.3) | Missense Mutation (SNP) | VAF 82/406 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV51484691; called by muse, mutect2, varscan2
- SLC30A6 | c.876T>G p.F292L | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.336); catalogued as rs140174805; called by muse, mutect2, varscan2
- SLC39A10 | c.183dup p.Y62Ifs*4 | Frame Shift Ins (INS) | VAF 64/368 reads (17%) | catalogued as rs771462597; called by mutect2, varscan2
- SLC4A3 | c.3088C>A p.L1030I | Missense Mutation (SNP) | VAF 108/594 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.823); catalogued as COSV56091252; called by muse, mutect2, varscan2
- SLC6A11 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 92/583 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV54394504; called by muse, mutect2, varscan2
- SLX4 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs775151113, COSV53560765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMCHD1 | c.4834A>G p.M1612V | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs370675357; called by muse, mutect2, varscan2
- SPRTN | c.1263dup p.I422Yfs*11 | Frame Shift Ins (INS) | VAF 44/314 reads (14%) | catalogued as rs567805129; called by mutect2, varscan2
- SPSB2 | c.599A>G p.Y200C | Missense Mutation (SNP) | VAF 64/860 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51290163; called by muse, mutect2
- SYNGAP1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 69/457 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.848); catalogued as rs536084145; called by muse, mutect2, varscan2
- TBC1D25 | c.476C>T p.T159M | Missense Mutation (SNP) | VAF 202/392 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.335); catalogued as rs781783909, COSV100952118; called by muse, mutect2, varscan2
- TEAD3 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 64/409 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268720847, COSV58817567; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 270/516 reads (52%) | catalogued as rs782753958; called by mutect2, varscan2
- THBS4 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 65/497 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749062616, COSV63467676; called by muse, mutect2, varscan2
- TIAM2 | c.3157C>T p.Q1053* | Nonsense Mutation (SNP) | VAF 18/309 reads (6%) | catalogued as rs552342373; called by muse, mutect2
- TLK2 | c.593A>C p.Q198P | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs769841221; called by muse, mutect2, varscan2
- TMED9 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 41/309 reads (13%) | catalogued as rs1406417802, COSV104409241; called by muse, varscan2
- TMEM52B | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 55/409 reads (13%) | catalogued as rs769702735, COSV100046501; called by muse, mutect2, varscan2
- TRIML1 | c.127A>G p.S43G | Missense Mutation (SNP) | VAF 79/483 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as COSV60195644; called by muse, mutect2, varscan2
- TSC22D1 | c.1099A>G p.M367V | Missense Mutation (SNP) | VAF 75/456 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs761224810; called by muse, mutect2, varscan2
- TSHZ2 | c.382G>T p.V128F | Missense Mutation (SNP) | VAF 84/531 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100295715; called by muse, mutect2, varscan2
- TTC34 | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 215/728 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1041659014; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 42/223 reads (19%) | catalogued as rs763254614; called by mutect2, varscan2
- UGGT2 | c.3139C>T p.L1047F | Missense Mutation (SNP) | VAF 69/398 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65075985; called by muse, mutect2, varscan2
- WDR33 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 26/370 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV59248554; called by muse, mutect2
- WDR59 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 63/378 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50933106; called by muse, mutect2, varscan2
- ZDHHC24 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 54/745 reads (7%) | catalogued as rs747432462, COSV60080186; called by muse, mutect2
- ZNF132 | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 74/693 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.283); catalogued as COSV99571036; called by muse, mutect2, varscan2
- ZNF140 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 165/573 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as rs1446770586; called by muse, mutect2, varscan2
- ZNF418 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 61/536 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as rs541471058, COSV68675925; called by muse, mutect2, varscan2
- ZNF469 | c.3374C>T p.A1125V (on ENST00000437464; = p.A1153V on NM_001367624.2) | Missense Mutation (SNP) | VAF 138/795 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs779180717; called by muse, mutect2, varscan2
- ZNF548 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 63/533 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs751437947; called by muse, mutect2, varscan2
- ZNF600 | c.1828T>C p.Y610H | Missense Mutation (SNP) | VAF 77/626 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV57741616; called by muse, mutect2, varscan2
- ZNF781 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 74/670 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs772286028, COSV62201701; called by muse, mutect2, varscan2
- ZNF813 | c.1015A>G p.T339A | Missense Mutation (SNP) | VAF 29/848 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.028); catalogued as rs1230900832; called by muse, mutect2
- ZNF829 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 41/392 reads (10%) | catalogued as COSV104430043; called by muse, mutect2
- ZNF835 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 83/738 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs778542856; called by muse, mutect2, varscan2
- ABCC1 | c.1301T>C p.F434S | Missense Mutation (SNP) | VAF 77/591 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACACB | c.3378G>A p.M1126I | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- ADAMTS5 | c.2637G>A p.W879* | Nonsense Mutation (SNP) | VAF 26/454 reads (6%) | called by muse, mutect2
- ADIPOQ | c.592T>C p.S198P | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD30BL | c.215A>G p.K72R | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, varscan2
- APOLD1 | c.781T>C p.S261P (on ENST00000326765 / NM_001130415.2; = p.S230P on NM_030817.3) | Missense Mutation (SNP) | VAF 24/554 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.102); called by muse, mutect2
- ARFGEF1 | c.4456T>C p.Y1486H | Missense Mutation (SNP) | VAF 60/350 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1A | c.3216dup p.W1073Mfs*32 | Frame Shift Ins (INS) | VAF 104/363 reads (29%) | called by mutect2, pindel, varscan2
- ARMT1 | c.1279T>C p.W427R | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARSG | c.745C>A p.H249N | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ART5 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 80/573 reads (14%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- ATP8B2 | c.3640A>C p.S1214R (on ENST00000672630; = p.S1181R on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/415 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAT2 | c.917A>G p.Q306R | Missense Mutation (SNP) | VAF 65/487 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCKDK | c.761T>C p.I254T | Missense Mutation (SNP) | VAF 73/499 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- BCL9 | c.3483dup p.Q1162Afs*41 | Frame Shift Ins (INS) | VAF 82/632 reads (13%) | called by mutect2, pindel, varscan2
- BORCS6 | c.1012C>A p.L338M | Missense Mutation (SNP) | VAF 99/558 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD4 | c.2999A>G p.Q1000R | Missense Mutation (SNP) | VAF 50/374 reads (13%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRD8 | c.221C>T p.T74I | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- BRD9 | c.1422G>T p.K474N | Missense Mutation (SNP) | VAF 64/407 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- BTNL3 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA1B | c.4211C>A p.P1404H | Missense Mutation (SNP) | VAF 81/472 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC106 | c.338G>A p.G113E | Missense Mutation (SNP) | VAF 264/677 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CD1E | c.993del p.K331Nfs*47 | Frame Shift Del (DEL) | VAF 54/361 reads (15%) | called by mutect2, pindel, varscan2
- CDK14 | c.889T>C p.Y297H (on ENST00000380050 / NM_001287135.2; = p.Y279H on NM_012395.3) | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP112 | c.2399A>G p.N800S (on ENST00000392769 / NM_001353127.1; = p.N56S on NM_001037325.3) | Missense Mutation (SNP) | VAF 37/320 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CFAP94 | c.512A>G p.Q171R (on ENST00000320267 / NM_001352064.2; = p.Q177R on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/510 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- CHD1L | c.640T>C p.Y214H | Missense Mutation (SNP) | VAF 58/374 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CHD7 | c.1259T>C p.I420T | Missense Mutation (SNP) | VAF 38/608 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); called by muse, mutect2
- CHRD | c.2179T>C p.S727P | Missense Mutation (SNP) | VAF 89/524 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CHRNA2 | c.1423T>C p.Y475H | Missense Mutation (SNP) | VAF 69/485 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CHRNA4 | c.1229T>C p.V410A | Missense Mutation (SNP) | VAF 81/570 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST7 | c.1340A>C p.E447A | Missense Mutation (SNP) | VAF 338/557 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CLIC3 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 85/538 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL19A1 | c.1359A>C p.E453D | Missense Mutation (SNP) | VAF 37/292 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- COPA | c.512dup p.N171Kfs*18 | Frame Shift Ins (INS) | VAF 54/302 reads (18%) | called by mutect2, varscan2
- CPA5 | c.1270C>A p.L424I | Missense Mutation (SNP) | VAF 69/411 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CPS1 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 54/328 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CRNN | c.1161G>T p.W387C | Missense Mutation (SNP) | VAF 89/603 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- DACT3 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 117/960 reads (12%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- DCAF12L2 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 339/563 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DDAH2 | c.120dup p.A41Sfs*11 | Frame Shift Ins (INS) | VAF 166/900 reads (18%) | called by mutect2, pindel, varscan2
- DDX3Y | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- DDX50 | c.1589C>A p.A530D | Missense Mutation (SNP) | VAF 38/287 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DISP1 | c.1090A>G p.R364G | Missense Mutation (SNP) | VAF 90/436 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, varscan2
- DMAC1 | c.91A>G p.T31A | Missense Mutation (SNP) | VAF 59/823 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- DNMT1 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 16/424 reads (4%) | called by muse, mutect2
- DSTYK | c.752C>A p.A251E | Missense Mutation (SNP) | VAF 53/449 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- DTWD1 | c.691del p.T231Qfs*29 | Frame Shift Del (DEL) | VAF 24/125 reads (19%) | called by mutect2, pindel, varscan2
- DYRK1A | c.910A>G p.K304E | Missense Mutation (SNP) | VAF 71/388 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EFCAB3 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 92/487 reads (19%) | called by muse, mutect2, varscan2
- EIF4G3 | c.2062A>G p.T688A | Missense Mutation (SNP) | VAF 88/316 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF5B | c.447dup p.A150Sfs*2 | Frame Shift Ins (INS) | VAF 46/460 reads (10%) | called by mutect2, pindel
- ELAVL1 | c.724T>C p.S242P | Missense Mutation (SNP) | VAF 74/430 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ELMO2 | c.1463A>G p.K488R | Missense Mutation (SNP) | VAF 54/404 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ENTPD3 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- EP300 | c.6076A>G p.N2026D | Missense Mutation (SNP) | VAF 77/589 reads (13%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- EPHX2 | c.1263dup p.V422Sfs*3 | Frame Shift Ins (INS) | VAF 68/476 reads (14%) | called by mutect2, pindel, varscan2
- ERO1A | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 75/446 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESPNL | c.2330A>T p.E777V | Missense Mutation (SNP) | VAF 46/760 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.15); called by muse, mutect2
- FADS1 | c.545T>C p.M182T | Missense Mutation (SNP) | VAF 74/506 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- FAM111B | c.847del p.I283Lfs*16 | Frame Shift Del (DEL) | VAF 51/340 reads (15%) | called by mutect2, pindel, varscan2
- FAT3 | c.3755C>T p.P1252L | Missense Mutation (SNP) | VAF 73/451 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT3 | c.6610C>A p.P2204T | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- FDX2 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 76/389 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FGL2 | c.189dup p.T65Dfs*27 | Frame Shift Ins (INS) | VAF 78/496 reads (16%) | called by mutect2, pindel, varscan2
- FRY | c.8057G>A p.S2686N | Missense Mutation (SNP) | VAF 81/518 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- FUT6 | c.682_683insA p.L228Hfs*170 | Frame Shift Ins (INS) | VAF 103/743 reads (14%) | called by mutect2, pindel, varscan2
- GABRG2 | c.784T>A p.W262R (on ENST00000361925 / NM_001375343.1; = p.W222R on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/495 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GBE1 | c.2011dup p.S671Ffs*2 | Frame Shift Ins (INS) | VAF 38/340 reads (11%) | called by mutect2, varscan2
- GLDN | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 30/702 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2
- GNAS | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 97/560 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- GOLGA6L2 | c.997C>A p.Q333K | Missense Mutation (SNP) | VAF 98/784 reads (13%) | SIFT tolerated, low confidence (0.06); called by muse, mutect2, varscan2
- GPR45 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 77/519 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM5 | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 67/536 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, varscan2
- GSC2 | c.239dup p.E81Rfs*72 | Frame Shift Ins (INS) | VAF 24/187 reads (13%) | called by mutect2, pindel, varscan2
- H1-5 | c.575A>T p.K192M | Missense Mutation (SNP) | VAF 91/589 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- H4C5 | c.193A>G p.N65D | Missense Mutation (SNP) | VAF 63/457 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- HDAC6 | c.2302G>T p.G768C | Missense Mutation (SNP) | VAF 227/399 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- HELQ | c.2593A>G p.S865G | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGF1R | c.2732_2733dup p.G912Lfs*26 | Frame Shift Ins (INS) | VAF 109/395 reads (28%) | called by mutect2, varscan2
- IGSF22 | c.1453G>T p.G485C | Missense Mutation (SNP) | VAF 75/501 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IL11 | c.509dup p.I171Hfs*16 | Frame Shift Ins (INS) | VAF 92/778 reads (12%) | called by mutect2, varscan2
- INPPL1 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 105/555 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- INSIG1 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 43/350 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- IRF9 | c.1157A>G p.Q386R | Missense Mutation (SNP) | VAF 111/667 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ITGAE | c.1370A>G p.Q457R | Missense Mutation (SNP) | VAF 60/407 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- JMY | c.2849T>C p.L950P | Missense Mutation (SNP) | VAF 58/429 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- KANSL2 | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNMB4 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 24/739 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.046); called by muse, mutect2
- KDM2B | c.3754A>G p.T1252A | Missense Mutation (SNP) | VAF 68/487 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KLF3 | c.536_544+7del p.X179_splice | Splice Site (DEL) | VAF 34/284 reads (12%) | called by mutect2, pindel
- KLF3 | c.654dup p.M220Nfs*44 | Frame Shift Ins (INS) | VAF 33/294 reads (11%) | called by mutect2, pindel, varscan2
- KRT38 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 79/580 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LAMA1 | c.8840G>A p.G2947D | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMB1 | c.2237T>C p.V746A | Missense Mutation (SNP) | VAF 67/465 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- LONP1 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 61/352 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- LRRC75A | c.517C>T p.P173S (on ENST00000470794 / NM_001113567.3; = p.P134L on NM_207387.4) | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- LRWD1 | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 86/487 reads (18%) | called by muse, mutect2, varscan2
- LYPD3 | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 38/596 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.157); called by muse, mutect2
- LZTS1 | c.1785G>C p.E595D | Missense Mutation (SNP) | VAF 37/349 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MAP4K1 | c.1681del p.H561Tfs*80 | Frame Shift Del (DEL) | VAF 56/471 reads (12%) | called by mutect2, pindel, varscan2
- MARCHF6 | c.833T>G p.L278R | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MBD4 | c.298G>C p.G100R | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEIS1 | c.1103T>A p.I368N | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- MEP1A | c.1144G>T p.G382* | Nonsense Mutation (SNP) | VAF 41/266 reads (15%) | called by muse, mutect2, varscan2
- MEX3B | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 208/619 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- MLXIPL | c.2095T>C p.Y699H | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MS4A8 | c.29T>A p.V10E | Missense Mutation (SNP) | VAF 62/394 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MYBPC3 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 20/380 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYCBP2 | c.8744A>G p.D2915G (on ENST00000357337; = p.D2953G on NM_015057.5) | Missense Mutation (SNP) | VAF 67/400 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYO15B | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 66/401 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- MYOD1 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 58/404 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- NAA35 | c.1687dup p.T563Nfs*29 | Frame Shift Ins (INS) | VAF 36/242 reads (15%) | called by mutect2, varscan2
- NAV2 | c.1285_1302delinsT p.K429Wfs*7 (on ENST00000396087 / NM_001244963.2; = p.K406Wfs*7 on NM_145117.5) | Frame Shift Del (DEL) | VAF 95/592 reads (16%) | called by pindel, varscan2*
- NINL | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 66/379 reads (17%) | called by muse, mutect2, varscan2
- NIPA2 | c.583T>C p.C195R | Missense Mutation (SNP) | VAF 75/546 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- NOS1AP | c.1132A>G p.I378V | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.437); called by muse, varscan2
- NPAS1 | c.1637_1638dup p.A547Pfs*? | Frame Shift Ins (INS) | VAF 119/1075 reads (11%) | called by mutect2, pindel, varscan2
- NUP133 | c.209A>C p.H70P | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- NUP160 | c.3043A>C p.S1015R | Missense Mutation (SNP) | VAF 65/426 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- OMG | c.1085T>C p.V362A | Missense Mutation (SNP) | VAF 75/478 reads (16%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR13C8 | c.209A>G p.D70G | Missense Mutation (SNP) | VAF 81/516 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- OR14J1 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 77/505 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR2AG1 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR4E2 | c.742G>T p.A248S | Missense Mutation (SNP) | VAF 64/455 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR4Q2 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 66/438 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52E2 | c.638C>A p.T213K | Missense Mutation (SNP) | VAF 68/445 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2
- OR52N1 | c.778A>G p.T260A | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2
- OR5R1 | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 72/469 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- PFAS | c.3520C>A p.P1174T | Missense Mutation (SNP) | VAF 66/581 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIK3R4 | c.1469C>A p.A490E | Missense Mutation (SNP) | VAF 39/264 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIP5K1C | c.1444A>G p.S482G | Missense Mutation (SNP) | VAF 112/747 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PLCE1 | c.5586T>A p.D1862E | Missense Mutation (SNP) | VAF 67/406 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCXD1 | c.970T>G p.*324Gext*22 | Nonstop Mutation (SNP) | VAF 57/461 reads (12%) | called by muse, mutect2, varscan2
- PLEC | c.10099G>C p.A3367P (on ENST00000322810 / NM_201380.4; = p.A3257P on NM_000445.5) | Missense Mutation (SNP) | VAF 117/755 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- PMS2 | c.1357_1363del p.M453Lfs*14 | Frame Shift Del (DEL) | VAF 55/388 reads (14%) | called by mutect2, pindel, varscan2
- POU3F3 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); called by muse, varscan2
- PPFIA3 | c.2903C>A p.P968H | Missense Mutation (SNP) | VAF 80/631 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PRMT5 | c.1186A>G p.N396D | Missense Mutation (SNP) | VAF 45/305 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PRPF31 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 90/966 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2
- PRR14L | c.6320T>C p.V2107A | Missense Mutation (SNP) | VAF 63/450 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- PSMC6 | c.451G>T p.G151W (on ENST00000612399; = p.G137W on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSMD1 | c.390G>T p.L130F | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PTP4A1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2
- PTPRC | c.2765T>C p.L922S | Missense Mutation (SNP) | VAF 46/348 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RAB27A | c.248G>C p.S83T | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.994); called by muse, mutect2
- RAB39A | c.591del p.F197Lfs*13 | Frame Shift Del (DEL) | VAF 61/413 reads (15%) | called by mutect2, pindel, varscan2
- RABGGTA | c.1476G>T p.Q492H | Missense Mutation (SNP) | VAF 66/452 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- RFC5 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 45/442 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RGL4 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 46/368 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RGPD4 | c.85G>T p.G29* | Nonsense Mutation (SNP) | VAF 25/204 reads (12%) | called by muse, mutect2, varscan2
- RIF1 | c.4169dup p.V1391Sfs*11 | Frame Shift Ins (INS) | VAF 41/385 reads (11%) | called by mutect2, pindel, varscan2
- RIMS4 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.035); called by muse, varscan2
- RMI1 | c.536T>A p.V179D | Missense Mutation (SNP) | VAF 28/500 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- RNF151 | c.339C>A p.C113* | Nonsense Mutation (SNP) | VAF 53/692 reads (8%) | called by muse, mutect2
- ROCK1 | c.3921dup p.W1308Mfs*11 | Frame Shift Ins (INS) | VAF 43/258 reads (17%) | called by mutect2, varscan2
- RPS6KA2 | c.2162A>G p.Q721R | Missense Mutation (SNP) | VAF 41/357 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- RSBN1L | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 100/651 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RSPO3 | c.142T>C p.C48R | Missense Mutation (SNP) | VAF 74/435 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SAMD9 | c.2258A>G p.E753G | Missense Mutation (SNP) | VAF 62/446 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SCRN3 | c.709T>A p.S237T | Missense Mutation (SNP) | VAF 23/414 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2
- SECISBP2 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 21/415 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.14); called by muse, mutect2
- SEMA3D | c.338G>C p.R113P | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- SFMBT2 | c.1511A>G p.K504R | Missense Mutation (SNP) | VAF 34/304 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SIAH2 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 64/425 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SIPA1L3 | c.10T>C p.Y4H | Missense Mutation (SNP) | VAF 65/568 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- SLC13A3 | c.1328del p.C443Lfs*60 | Frame Shift Del (DEL) | VAF 24/211 reads (11%) | called by mutect2, pindel, varscan2
- SLC1A7 | c.668T>G p.L223R | Missense Mutation (SNP) | VAF 121/392 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC26A11 | c.213A>C p.E71D | Missense Mutation (SNP) | VAF 67/398 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- SLC35G1 | c.319T>G p.F107V (on ENST00000427197 / NM_001134658.3; = p.F106V on NM_153226.4) | Missense Mutation (SNP) | VAF 34/418 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- SLC47A1 | c.1713A>G p.*571Wext*10 | Nonstop Mutation (SNP) | VAF 9/240 reads (4%) | called by muse, mutect2
- SPAG6 | c.208A>G p.N70D | Missense Mutation (SNP) | VAF 68/458 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SREBF1 | c.2197dup p.A733Gfs*96 | Frame Shift Ins (INS) | VAF 31/200 reads (16%) | called by mutect2, pindel, varscan2
- ST8SIA4 | c.503+1G>A p.X168_splice | Splice Site (SNP) | VAF 38/192 reads (20%) | called by muse, mutect2, varscan2
- STAB2 | c.4523G>T p.G1508V | Missense Mutation (SNP) | VAF 46/336 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STAU2 | c.1529A>G p.Q510R (on ENST00000524300 / NM_001164380.2; = p.Q478R on NM_014393.2) | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- STPG1 | c.206C>A p.P69H (on ENST00000337248 / NM_001199013.2; = p.P22H on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/248 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STRN | c.1262T>C p.L421P | Missense Mutation (SNP) | VAF 72/437 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- STXBP1 | c.1232A>G p.Y411C | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- SUN1 | c.287G>A p.S96N (on ENST00000405266 / NM_001367651.1; = p.S46N on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/340 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TASP1 | c.1108T>C p.W370R | Missense Mutation (SNP) | VAF 43/371 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TBX22 | c.1447T>C p.S483P | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2
- TEX15 | c.5392G>A p.E1798K (on ENST00000256246; = p.E2181K on NM_001350162.2) | Missense Mutation (SNP) | VAF 67/471 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX55 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 21/438 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.808); called by muse, mutect2
- TGFB3 | c.698A>G p.Q233R | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMCO1 | c.454C>A p.L152I (on ENST00000612311 / NM_001256164.1; = p.L101I on NM_019026.6) | Missense Mutation (SNP) | VAF 55/304 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TMEM145 | c.802A>T p.T268S | Missense Mutation (SNP) | VAF 55/410 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TMEM251 | c.473T>G p.L158R (on ENST00000415050 / NM_001098621.4; = p.L126R on NM_015676.3) | Missense Mutation (SNP) | VAF 62/436 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TMEM271 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TMPRSS15 | c.1799G>A p.G600D | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- TNRC6A | c.5019G>A p.W1673* | Nonsense Mutation (SNP) | VAF 71/426 reads (17%) | called by muse, mutect2, varscan2
- TRAF1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 13/379 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.16); called by muse, mutect2
- TRIM32 | c.1413A>C p.K471N | Missense Mutation (SNP) | VAF 68/510 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- TRIM4 | c.1031C>G p.A344G | Missense Mutation (SNP) | VAF 74/453 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TRIML1 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 63/372 reads (17%) | called by muse, mutect2, varscan2
- TSPAN31 | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- TST | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 69/535 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- UACA | c.1534A>G p.K512E | Missense Mutation (SNP) | VAF 91/320 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ULBP1 | c.81G>T p.W27C | Missense Mutation (SNP) | VAF 41/451 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- UQCRFS1 | c.643G>T p.G215C | Missense Mutation (SNP) | VAF 76/599 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP42 | c.3706_3707dup p.K1237Rfs*92 | Frame Shift Ins (INS) | VAF 54/384 reads (14%) | called by mutect2, varscan2
- UTP25 | c.1351T>C p.S451P | Missense Mutation (SNP) | VAF 64/491 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VANGL2 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VPS13C | c.8697C>G p.N2899K (on ENST00000644861 / NM_020821.3; = p.N2856K on NM_017684.5) | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- VWDE | c.2597T>C p.I866T | Missense Mutation (SNP) | VAF 68/438 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- WDFY3 | c.3571G>A p.G1191R | Missense Mutation (SNP) | VAF 77/559 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- XKR5 | c.976T>C p.W326R | Missense Mutation (SNP) | VAF 64/528 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZC3H14 | c.1420C>A p.L474M | Missense Mutation (SNP) | VAF 52/394 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF17 | c.595T>C p.F199L | Missense Mutation (SNP) | VAF 75/799 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF334 | c.444A>C p.E148D | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF347 | c.776G>T p.S259I | Missense Mutation (SNP) | VAF 82/680 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF419 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 82/821 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2
- ZNF584 | c.1075T>C p.C359R | Missense Mutation (SNP) | VAF 89/724 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF608 | c.475A>G p.S159G | Missense Mutation (SNP) | VAF 95/527 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF611 | c.1444T>C p.Y482H | Missense Mutation (SNP) | VAF 64/584 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF629 | c.1753A>G p.M585V | Missense Mutation (SNP) | VAF 125/627 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF713 | c.212T>C p.L71S (on ENST00000633730 / NM_001366796.2; = p.L84S on NM_182633.3) | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF793 | c.1087G>T p.G363* | Nonsense Mutation (SNP) | VAF 32/733 reads (4%) | called by muse, mutect2
- ZSWIM8 | c.2151G>T p.E717D | Missense Mutation (SNP) | VAF 67/534 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AARS2 | c.2211C>T p.A737= | Silent (SNP) | VAF 58/390 reads (15%) | called by muse, mutect2, varscan2
- ADAMTS16 | c.1924C>A p.R642= | Silent (SNP) | VAF 59/383 reads (15%) | called by muse, mutect2, varscan2
- ADD2 | c.159C>T p.R53= | Silent (SNP) | VAF 32/487 reads (7%) | catalogued as rs1553374388, COSV52460608; called by muse, mutect2
- APC2 | c.5049C>T p.S1683= | Silent (SNP) | VAF 98/689 reads (14%) | catalogued as rs758774931; called by muse, mutect2, varscan2
- ARMC6 | c.708T>C p.T236= (on ENST00000392336; = p.T211= on NM_033415.4) | Silent (SNP) | VAF 77/549 reads (14%) | called by muse, mutect2, varscan2
- BHLHA9 | c.75C>G p.G25= | Silent (SNP) | VAF 69/580 reads (12%) | catalogued as rs1381197592; called by muse, mutect2, varscan2
- BRPF3 | c.3093G>A p.T1031= | Silent (SNP) | VAF 51/347 reads (15%) | catalogued as rs757044879; called by muse, mutect2, varscan2
- C9orf72 | c.1377A>G p.L459= | Silent (SNP) | VAF 53/403 reads (13%) | called by muse, mutect2, varscan2
- CACNA1I | c.1737C>T p.S579= | Silent (SNP) | VAF 102/640 reads (16%) | catalogued as rs1388087367; called by muse, varscan2
- CASKIN1 | c.2511C>A p.P837= | Silent (SNP) | VAF 119/775 reads (15%) | called by muse, mutect2, varscan2
- CCDC65 | c.1338T>C p.S446= | Silent (SNP) | VAF 169/673 reads (25%) | called by muse, mutect2, varscan2
- CCDC7 | c.2607A>C p.S869= | Silent (SNP) | VAF 48/269 reads (18%) | called by muse, mutect2, varscan2
- CDH22 | c.1110C>T p.A370= | Silent (SNP) | VAF 92/586 reads (16%) | catalogued as rs1370698856; called by muse, mutect2, varscan2
- CDT1 | c.1557C>A p.T519= | Silent (SNP) | VAF 45/694 reads (6%) | called by muse, mutect2
- CEACAM16 | c.369C>T p.H123= | Silent (SNP) | VAF 49/426 reads (12%) | catalogued as rs757791182, COSV69186151; called by muse, mutect2, varscan2
- CHRNA10 | c.753G>A p.S251= | Silent (SNP) | VAF 58/606 reads (10%) | catalogued as rs770133301; called by muse, mutect2
- CNBD1 | c.1026A>G p.K342= | Silent (SNP) | VAF 44/339 reads (13%) | catalogued as rs941002692, COSV73073810; called by muse, mutect2, varscan2
- COL14A1 | c.2769C>A p.T923= | Silent (SNP) | VAF 50/295 reads (17%) | called by muse, mutect2, varscan2
- COL19A1 | c.642A>C p.R214= | Silent (SNP) | VAF 23/376 reads (6%) | called by muse, mutect2
- CRTAC1 | c.42G>A p.P14= | Silent (SNP) | VAF 38/252 reads (15%) | catalogued as rs780537531, COSV100085291; called by muse, mutect2, varscan2
- DCHS1 | c.4965C>T p.S1655= | Silent (SNP) | VAF 80/521 reads (15%) | called by muse, mutect2, varscan2
- DCHS1 | c.3099C>A p.T1033= | Silent (SNP) | VAF 89/622 reads (14%) | catalogued as rs755242978; called by muse, mutect2, varscan2
- DLGAP1 | c.768C>T p.D256= | Silent (SNP) | VAF 83/505 reads (16%) | catalogued as rs1472291921; called by muse, mutect2, varscan2
- DNAJC16 | c.1140G>A p.S380= | Silent (SNP) | VAF 81/283 reads (29%) | catalogued as rs774438587, COSV101012639; called by muse, mutect2, varscan2
- EHD2 | c.93G>A p.T31= | Silent (SNP) | VAF 64/828 reads (8%) | catalogued as rs1248524605; called by muse, mutect2
- ELK3 | c.708C>A p.A236= | Silent (SNP) | VAF 89/754 reads (12%) | called by muse, mutect2, varscan2
- FARP2 | c.426G>A p.L142= | Silent (SNP) | VAF 35/237 reads (15%) | called by muse, mutect2, varscan2
- FBXL7 | c.993C>A p.V331= | Silent (SNP) | VAF 100/619 reads (16%) | called by muse, mutect2, varscan2
- FLG | c.11157G>A p.Q3719= | Silent (SNP) | VAF 108/693 reads (16%) | called by muse, mutect2, varscan2
- FMN2 | c.3648G>C p.G1216= | Silent (SNP) | VAF 72/490 reads (15%) | called by muse, mutect2, varscan2
- GANAB | c.1129C>A p.R377= | Silent (SNP) | VAF 82/392 reads (21%) | catalogued as COSV60461461, COSV60462186; called by muse, mutect2, varscan2
- GOLGA6B | c.1440T>C p.A480= | Silent (SNP) | VAF 133/289 reads (46%) | called by muse, mutect2, varscan2
- GOLT1A | c.315C>A p.A105= | Silent (SNP) | VAF 65/415 reads (16%) | called by muse, mutect2, varscan2
- GSR | c.951A>G p.L317= | Silent (SNP) | VAF 77/529 reads (15%) | called by muse, mutect2, varscan2
- HIVEP2 | c.7314T>C p.P2438= | Silent (SNP) | VAF 56/304 reads (18%) | called by muse, mutect2, varscan2
- IGFBP2 | c.864C>T p.P288= | Silent (SNP) | VAF 74/473 reads (16%) | called by muse, mutect2, varscan2
- KLHL2 | c.220C>T p.L74= | Silent (SNP) | VAF 50/608 reads (8%) | called by muse, mutect2
- KLHL29 | c.594G>A p.P198= | Silent (SNP) | VAF 93/664 reads (14%) | catalogued as rs753127612; called by muse, mutect2, varscan2
- LDHD | c.189C>T p.C63= | Silent (SNP) | VAF 60/373 reads (16%) | catalogued as rs1199190305, COSV55580821; called by muse, mutect2, varscan2
- LILRA4 | c.543C>T p.P181= | Silent (SNP) | VAF 102/1161 reads (9%) | called by muse, mutect2
- LRP2 | c.9222G>A p.T3074= | Silent (SNP) | VAF 84/521 reads (16%) | catalogued as rs752426380, COSV55556444; called by muse, mutect2, varscan2
- LTBP4 | c.2145C>A p.A715= (on ENST00000308370 / NM_001042544.1; = p.A678= on NM_003573.2) | Silent (SNP) | VAF 93/789 reads (12%) | called by muse, mutect2, varscan2
- MARF1 | c.3864C>T p.Y1288= | Silent (SNP) | VAF 94/628 reads (15%) | catalogued as rs763795221; called by muse, mutect2, varscan2
- MFSD1 | c.136C>T p.L46= | Silent (SNP) | VAF 65/511 reads (13%) | catalogued as rs759982429, COSV51839197; called by muse, mutect2, varscan2
- MSLN | c.1320C>T p.T440= (on ENST00000382862 / NM_013404.4; = p.T432= on NM_005823.6) | Silent (SNP) | VAF 79/566 reads (14%) | called by muse, mutect2, varscan2
- MYO1H | c.2133T>C p.H711= | Silent (SNP) | VAF 30/289 reads (10%) | called by muse, mutect2, varscan2
- NEB | c.13308G>T p.T4436= | Silent (SNP) | VAF 32/312 reads (10%) | called by muse, mutect2
- NEIL2 | c.294T>C p.L98= | Silent (SNP) | VAF 61/603 reads (10%) | called by muse, mutect2, varscan2
- NIM1K | c.303C>T p.A101= | Silent (SNP) | VAF 25/235 reads (11%) | called by muse, mutect2, varscan2
- NMNAT3 | c.492C>T p.C164= (on ENST00000296202 / NM_001320512.1; = p.C127= on NM_178177.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/551 reads (12%) | catalogued as rs372691677; called by muse, mutect2, varscan2
- NOL10 | c.915A>T p.I305= | Silent (SNP) | VAF 11/350 reads (3%) | called by muse, mutect2
- OR10X1 | c.807T>G p.G269= | Silent (SNP) | VAF 76/491 reads (15%) | catalogued as COSV63767931; called by muse, mutect2, varscan2
- PCDHA6 | c.237G>A p.L79= | Silent (SNP) | VAF 105/761 reads (14%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1623C>T p.S541= | Silent (SNP) | VAF 107/896 reads (12%) | catalogued as COSV50691394; called by muse, mutect2, varscan2
- PCDHGA2 | c.1344C>T p.N448= | Silent (SNP) | VAF 96/537 reads (18%) | catalogued as rs749272977, COSV53909517; called by muse, mutect2, varscan2
- PLD5 | c.18C>T p.H6= | Silent (SNP) | VAF 76/398 reads (19%) | called by muse, mutect2, varscan2
- PLXNA4 | c.1248C>T p.S416= | Silent (SNP) | VAF 64/481 reads (13%) | catalogued as rs374767499, COSV58126348; called by muse, mutect2, varscan2
- POTEA | c.267C>T p.G89= | Silent (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- PRKG2 | c.402T>C p.Y134= | Silent (SNP) | VAF 74/450 reads (16%) | called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.1167A>G p.K389= (on ENST00000421990 / NM_001136042.2; = p.K371= on NM_025267.3) | Silent (SNP) | VAF 50/334 reads (15%) | called by muse, mutect2, varscan2
- QKI | c.939G>A p.A313= | Silent (SNP) | VAF 40/249 reads (16%) | catalogued as rs765276688, COSV51701071, COSV99275639; called by muse, mutect2, varscan2
- RABGAP1 | c.2859A>G p.T953= | Silent (SNP) | VAF 51/340 reads (15%) | called by muse, mutect2, varscan2
- RND1 | c.489C>A p.I163= | Silent (SNP) | VAF 134/398 reads (34%) | called by muse, mutect2, varscan2
- RNF19A | c.180C>A p.P60= | Silent (SNP) | VAF 60/478 reads (13%) | catalogued as COSV100347837; called by muse, mutect2, varscan2
- SALL3 | c.936C>T p.A312= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs959247861; called by muse, mutect2, varscan2
- SBK2 | c.468G>A p.P156= | Silent (SNP) | VAF 78/1120 reads (7%) | catalogued as rs1034503621; called by muse, mutect2
- SCARA3 | c.204C>T p.A68= | Silent (SNP) | VAF 45/363 reads (12%) | catalogued as rs774339491; called by muse, mutect2, varscan2
- SCO1 | c.471T>C p.G157= | Silent (SNP) | VAF 57/488 reads (12%) | called by muse, mutect2, varscan2
- SCX | c.183C>T p.A61= | Silent (SNP) | VAF 33/236 reads (14%) | called by muse, mutect2, varscan2
- SLC11A1 | c.1296C>T p.N432= | Silent (SNP) | VAF 67/391 reads (17%) | catalogued as rs201092558, COSV51916252; called by muse, mutect2, varscan2
- SLC5A11 | c.1233G>A p.R411= | Silent (SNP) | VAF 66/343 reads (19%) | called by muse, mutect2, varscan2
- SLC8A1 | c.1728C>T p.T576= | Silent (SNP) | VAF 76/428 reads (18%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.1338A>G p.P446= | Silent (SNP) | VAF 67/513 reads (13%) | catalogued as rs1399204451; called by muse, mutect2, varscan2
- TBC1D4 | c.3426G>A p.E1142= | Silent (SNP) | VAF 51/414 reads (12%) | called by muse, mutect2, varscan2
- TBX22 | c.219C>G p.G73= | Silent (SNP) | VAF 94/276 reads (34%) | catalogued as COSV100960965; called by muse, mutect2, varscan2
- TCHH | c.5307C>T p.R1769= | Silent (SNP) | VAF 74/560 reads (13%) | catalogued as rs1296593384; called by muse, mutect2, varscan2
- TMEM178B | c.363C>T p.I121= | Silent (SNP) | VAF 72/397 reads (18%) | catalogued as rs1168487885; called by muse, mutect2, varscan2
- TTC34 | c.2451G>C p.G817= | Silent (SNP) | VAF 145/577 reads (25%) | called by muse, mutect2, varscan2
- TTI2 | c.885C>A p.A295= | Silent (SNP) | VAF 50/439 reads (11%) | called by muse, mutect2, varscan2
- UBR7 | c.402C>T p.Y134= | Silent (SNP) | VAF 52/291 reads (18%) | catalogued as rs1291962930; called by muse, mutect2, varscan2
- UPF1 | c.720C>A p.S240= | Silent (SNP) | VAF 77/489 reads (16%) | called by muse, mutect2, varscan2
- UPK1A | c.678C>A p.I226= | Silent (SNP) | VAF 57/488 reads (12%) | catalogued as COSV55878489, COSV99033226; called by muse, mutect2, varscan2
- VAX1 | c.411T>C p.L137= | Silent (SNP) | VAF 54/314 reads (17%) | called by muse, mutect2, varscan2
- VPS4A | c.699C>T p.C233= | Silent (SNP) | VAF 48/432 reads (11%) | catalogued as rs374250970; called by muse, mutect2, varscan2
- VWA3A | c.2028C>A p.T676= | Silent (SNP) | VAF 73/484 reads (15%) | called by muse, mutect2, varscan2
- XKR6 | c.519G>A p.S173= | Silent (SNP) | VAF 78/661 reads (12%) | called by muse, mutect2, varscan2
- ZC3H3 | c.1212C>T p.A404= | Silent (SNP) | VAF 110/795 reads (14%) | called by muse, mutect2, varscan2
- ZC3H7A | c.2256A>G p.E752= | Silent (SNP) | VAF 49/370 reads (13%) | called by muse, mutect2, varscan2
- ZIC4 | c.327G>T p.A109= | Silent (SNP) | VAF 140/650 reads (22%) | catalogued as COSV67170603; called by muse, mutect2, varscan2
- ZNF579 | c.912C>T p.G304= | Silent (SNP) | VAF 107/878 reads (12%) | called by muse, mutect2, varscan2
- ZNF687 | c.840C>A p.V280= | Silent (SNP) | VAF 77/519 reads (15%) | called by muse, mutect2, varscan2
- ZNF790 | c.1791C>T p.T597= | Silent (SNP) | VAF 51/436 reads (12%) | called by muse, mutect2, varscan2
- ZNF879 | c.963T>C p.C321= | Silent (SNP) | VAF 88/544 reads (16%) | called by muse, mutect2, varscan2
- AC090409.1 | n.236C>G | RNA (SNP) | VAF 34/416 reads (8%) | called by muse, mutect2
- BCAT1 | c.*1497A>G | 3'UTR (SNP) | VAF 52/416 reads (13%) | called by muse, mutect2, varscan2
- CRYAA | c.189+532_189+533del | Intron (DEL) | VAF 20/66 reads (30%) | catalogued as rs5844151; called by mutect2, varscan2
- DOCK7 | c.1801-1588C>T | Intron (SNP) | VAF 55/385 reads (14%) | called by muse, mutect2, varscan2
- GCK | c.46-5653C>T | Intron (SNP) | VAF 57/449 reads (13%) | catalogued as rs753381934, COSV61753649; called by muse, mutect2, varscan2
- MAP1A | c.-323T>C | 5'UTR (SNP) | VAF 117/384 reads (30%) | called by muse, mutect2, varscan2
- MAZ | c.*149A>G | 3'UTR (SNP) | VAF 44/303 reads (15%) | called by muse, mutect2, varscan2
- MFSD5 | chr12:53251861 C>A | 5'Flank (SNP) | VAF 78/551 reads (14%) | called by muse, mutect2, varscan2
- OBSCN | c.2653+2239G>A | Intron (SNP) | VAF 63/424 reads (15%) | catalogued as rs749644476; called by muse, mutect2, varscan2
- PLEC | c.524-731C>G | Intron (SNP) | VAF 17/463 reads (4%) | called by muse, mutect2
- RBM44 | chr2:237813627 G>A | 5'Flank (SNP) | VAF 46/365 reads (13%) | called by muse, mutect2, varscan2
- RIMBP2 | c.2362-1775G>T | Intron (SNP) | VAF 162/627 reads (26%) | called by muse, mutect2, varscan2
- SEPTIN4 | c.797+52A>C | Intron (SNP) | VAF 49/443 reads (11%) | called by muse, mutect2, varscan2
- SLC22A17 | n.1059G>A | RNA (SNP) | VAF 33/423 reads (8%) | catalogued as rs968923148, COSV52837807; called by muse, mutect2
- TTN | c.10361-5349G>A | Intron (SNP) | VAF 44/536 reads (8%) | catalogued as rs201766148, COSV60142904; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.10360+1253T>G | Intron (SNP) | VAF 59/434 reads (14%) | catalogued as COSV59861821, COSV59870423; called by muse, mutect2, varscan2
